Somatic mutation profile of tumor specimen 0DPHT2 from CCDI case PBCDRD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.4 years (891 days).
Specimen 0DPHT2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84365c1f-2a55-486d-8eb9-86cfa664502f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPHSZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/129aae51-83c7-49a6-9518-007e7890d10d

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.3811C>A p.P1271T | Missense Mutation (SNP) | VAF 111/529 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100314894; called by muse, mutect2, varscan2
- C1orf105 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 293/1258 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs768793316; called by muse, mutect2, varscan2
- EPX | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 386/910 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs761365538, COSV56599203; called by muse, mutect2, varscan2
- IARS2 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 460/1078 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs377432411; called by muse, mutect2, varscan2
- MPP5 | c.154C>G p.R52G | Missense Mutation (SNP) | VAF 49/1238 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as COSV55533014, COSV99906799; called by muse, mutect2
- UBLCP1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 155/1176 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs767226231; called by muse, mutect2, varscan2
- DRC7 | c.1359C>T p.L453= | Silent (SNP) | VAF 32/1022 reads (3%) | called by muse, mutect2
- PPARA | c.999G>A p.A333= | Silent (SNP) | VAF 586/606 reads (97%) | catalogued as rs563662966; called by muse, mutect2, varscan2
- AC073578.1 | n.557G>A | RNA (SNP) | VAF 11/262 reads (4%) | catalogued as rs1055897766; called by muse, mutect2
